Surgical pathology report (de-identified scan), TCGA case TCGA-A7-A6VW, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-A7-A6VW-01A (Primary Tumor).

ICD-O-3
Carcinoma, infiltrating duct
NOS 8500/3
Site @ Breast NOS C50.9
JW 7/25/13

Final Surgical Pathology Report

Procedure:

Diagnosis

- A. Sentinel lymph node, left axilla, biopsy: Two negative lymph nodes (0/2).
- B. Breast, left, excisional biopsy: Invasive ductal carcinoma, grade 3, size 3.0 cm in greatest dimension, close to the medial and inferior margins.

Microscopic Description:

Invasive carcinoma:

Histologic type: Ductal

Histologic grade: 3

Overall grade: 9/9

Architectural score: 3

Nuclear score: 3

Mitotic score: 3

Greatest dimension (pT2): Size 3.0 cm in greatest dimension
Specimen margins: Carcinoma is well-demarcated, and forms a discrete mass lesion that is less than 1 mm from the medial margin and 0.5 mm from the inferior margin.

Vessel invasion: Not identified

Ductal carcinoma in situ: Not identified.

Comment: Prior biopsy site identified.

Distant metastasis (pM): Unknown

Lymph nodes: Two negative sentinel lymph nodes, 0/2.

Prognostic markers: See previous core biopsy

Specimen

- A. Left axillary sentinel node
- B. Left breast biopsy

Clinical Information

Left breast cancer, yo BF with grade 3 IDC

Gross Description

- A. Received unfixed, labeled left axillary sentinel node, are two lymph nodes, the larger of which is 1.4 x 1.2 x 1.0 cm, bisected and submitted in blocks 1-2, and an additional node, 1.0 x 0.5 x 0.5 cm, bisected and submitted in block 3.
- B. Received unfixed in a container, labeled left breast, is a portion of fibrofatty tissue that is oriented and 6.0 cm anterior to posterior, 4.5 cm medial to lateral, and 2.3 cm superior to inferior. Margins are inked: inferior blue, superior black, medial yellow, lateral green. The specimen is serially sectioned from anterior to posterior. There is a 3.0 x 2.0 x 1.9 cm tumor present, adjacent to the medial and inferior margins. Representative sections, including the anterior and posterior shave margins, sequentially submitted in 8 blocks.

Local/Synchronous Primary, Noted		✓

Source: NCI Genomic Data Commons file 547c1c92-00d5-49c0-b796-6e3ec19c97b1 (TCGA-A7-A6VW.BE19CEFA-7A66-480C-BEC0-AF52F4C8A04C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).